Somatic mutation profile of tumor specimen TARGET-10-PASVPZ-09A (aliquot TARGET-10-PASVPZ-09A-01D) from TARGET case TARGET-10-PASVPZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,333 days).
Specimen TARGET-10-PASVPZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d0a5f3b-ac03-4dce-9b37-1eabcc0114d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASVPZ-10A (Blood Derived Normal), aliquot TARGET-10-PASVPZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7248625-b152-49dc-844f-38519f97dff0

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, 3'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFI1B | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554724691, COSV59745290; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.3406C>T p.R1136C (on ENST00000676605; = p.R1095C on NM_024790.6) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758825560, COSV51584889; called by muse, mutect2, varscan2
- NOTCH1 | c.7594T>G p.W2532G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53062561; called by muse, mutect2, varscan2
- USP7 | c.639_640insCCGAC p.V214Pfs*5 | Frame Shift Ins (INS) | VAF 30/104 reads (29%) | catalogued as COSV100784154; called by mutect2, varscan2
- CACNA1E | c.3523C>A p.P1175T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDT1 | c.1593C>A p.H531Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2
- LRRC71 | c.1340A>G p.E447G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- SENP7 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZBED6 | c.1275C>A p.Y425* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ZNF74 | c.597C>A p.D199E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2
- CNTNAP3 | c.2004C>T p.S668= | Silent (SNP) | VAF 18/22 reads (82%) | called by muse, mutect2, varscan2
- DRC7 | c.42C>T p.A14= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs752956898; called by muse, mutect2, varscan2
- KCNB2 | c.828G>A p.P276= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs749539173; called by muse, mutect2, varscan2
- POM121L2 | c.2316C>T p.P772= | Silent (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- KLHDC8B | c.*33C>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-66736C>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99339428; called by muse, mutect2, varscan2
